Somatic mutation profile of tumor specimen 32b962ad-4f52-4778-90eb-0ef7d5 (aliquot 32b962ad-4f52-4778-90eb-0ef7d5_D6) from CPTAC case 17OV017, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 32b962ad-4f52-4778-90eb-0ef7d5: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc4fdc5b-2a3a-4b24-9b2b-706d0096438e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 012ff650-0db2-41a2-a309-383835 (Blood Derived Normal), aliquot 012ff650-0db2-41a2-a309-383835_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cee3e0b-0965-4075-b4d7-d76bf9134e6e

The open-access MAF lists 42 somatic variants for this specimen: 32 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 6, Nonsense Mutation 3, Intron 2, Splice Site 1, 3'UTR 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TAF1 | c.3887T>C p.I1296T (on ENST00000373790 / NM_138923.4; = p.I1317T on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs864321627, CM151914, COSV52111070; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM29 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 94/292 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.895); catalogued as rs369224663; called by muse, mutect2, varscan2
- ATP2A3 | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 111/329 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99989838; called by muse, mutect2, varscan2
- CNTNAP5 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 58/273 reads (21%) | catalogued as rs1447158750, COSV70472787; called by muse, mutect2, varscan2
- CNTNAP5 | c.1793G>A p.G598E | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101443074; called by muse, mutect2, varscan2
- FNDC7 | c.1817C>T p.T606I | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs537445480; called by muse, mutect2, varscan2
- KLHL41 | c.1157C>A p.S386* | Nonsense Mutation (SNP) | VAF 54/113 reads (48%) | catalogued as COSV52929921; called by muse, mutect2, varscan2
- KSR2 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 46/261 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs778527288, COSV60370762; called by muse, mutect2, varscan2
- LAT | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs966408577; called by muse, mutect2, varscan2
- MBD1 | c.1151G>A p.R384Q (on ENST00000269468 / NM_001323950.1; = p.R328Q on NM_002384.2) | Missense Mutation (SNP) | VAF 112/687 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs1451074062, COSV53999551; called by muse, mutect2, varscan2
- NOD2 | c.2230C>T p.R744W | Missense Mutation (SNP) | VAF 84/1102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs140876663; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- PAPOLA | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); catalogued as rs1279318624; called by muse, mutect2, varscan2
- PRSS35 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1452509235, COSV63800474; called by muse, mutect2, varscan2
- SHF | c.303+1del p.X101_splice | Splice Site (DEL) | VAF 49/149 reads (33%) | catalogued as rs376594356, COSV52051842, COSV52052809; called by mutect2, pindel, varscan2
- ADAMTS3 | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BICRA | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ERBB4 | c.200G>A p.S67N | Missense Mutation (SNP) | VAF 131/607 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KCP | c.1373G>T p.C458F (on ENST00000620378; = p.C515F on NM_001366122.1) | Missense Mutation (SNP) | VAF 74/449 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- L3MBTL1 | c.1963G>A p.V655I (on ENST00000418998 / NM_001377303.1; = p.V565I on NM_015478.7) | Missense Mutation (SNP) | VAF 88/337 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- MAPK7 | c.1010C>A p.S337* | Nonsense Mutation (SNP) | VAF 116/420 reads (28%) | called by mutect2, varscan2
- MC1R | c.393C>G p.S131R | Missense Mutation (SNP) | VAF 194/451 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MED29 | c.427C>G p.L143V (on ENST00000615911; = p.L122V on NM_017592.4) | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- PALMD | c.784T>C p.Y262H | Missense Mutation (SNP) | VAF 78/322 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PIK3AP1 | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PIKFYVE | c.5501G>C p.R1834P | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PRPF6 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 114/515 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, varscan2
- SLA2 | c.342_357del p.G115Sfs*89 | Frame Shift Del (DEL) | VAF 78/325 reads (24%) | called by mutect2, pindel, varscan2
- SLCO1B1 | c.2051G>A p.G684E | Missense Mutation (SNP) | VAF 200/256 reads (78%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP1 | c.524C>A p.A175D | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VIM | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 101/341 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VWF | c.5939A>G p.K1980R | Missense Mutation (SNP) | VAF 103/1142 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.197); called by muse, mutect2
- ZNF831 | c.4663G>T p.D1555Y | Missense Mutation (SNP) | VAF 101/1044 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ABCC10 | c.1326C>A p.T442= (on ENST00000372530 / NM_001198934.2; = p.T399= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- EVC2 | c.3666A>G p.L1222= | Silent (SNP) | VAF 32/135 reads (24%) | catalogued as rs779697268; called by muse, mutect2, varscan2
- MUC3A | c.801T>C p.N267= | Silent (SNP) | VAF 83/403 reads (21%) | catalogued as rs1216692728; called by muse, mutect2, varscan2
- PLCH2 | c.2055C>T p.S685= | Silent (SNP) | VAF 49/275 reads (18%) | called by muse, mutect2, varscan2
- PRC1 | c.1542C>T p.P514= | Silent (SNP) | VAF 39/147 reads (27%) | catalogued as rs1010093046, COSV62694905; called by muse, mutect2, varscan2
- TTN | c.60015C>T p.L20005= (on ENST00000591111; = p.L12581= on NM_003319.4) | Silent (SNP) | VAF 42/188 reads (22%) | called by muse, mutect2, varscan2
- ANKH | c.96+243T>A | Intron (SNP) | VAF 58/202 reads (29%) | called by muse, mutect2, varscan2
- SDR39U1 | c.206+35G>A | Intron (SNP) | VAF 131/584 reads (22%) | called by muse, mutect2, varscan2
- XIST | n.7442T>C | RNA (SNP) | VAF 60/163 reads (37%) | called by muse, mutect2, varscan2
- ZNF230 | c.*1008dup | 3'UTR (INS) | VAF 38/113 reads (34%) | called by mutect2, pindel, varscan2
